Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8487, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8487-01A (Primary Tumor).

[page 1 of 3]
Case ID	Gross Description	Microscopic Description	Diagnosis Details
	Stomach with a polypoid tumour, up to 16 cm in its diameter, invades adjacent fatty tissue; fatty tissue lymph nodes are free of metastases; omentum - hyperemia; surgical margins are free of metastases.	Adenocarcinoma of the stomach G2-3. In the exofytic component the predominant type of growth is G2. In the endophytic component the predominate component is G3 with necrosis. Tumor invades into the perigastric fat. Fifteen lymph nodes demonstrated reactive hyperplasia. Omentum is hyperemic. Surgical margins are free of tumor elements.	Tumor Features: Exophytic (polypoid), Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

[page 2 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Total gastrectomy Tumor site: Antrum Tumor size: 16 x 0 x 0 cm Tumor features: Exophytic (polypoid) Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 0/15 positive for metastasis (Greater and lesser omentum 0/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

	ID

[page 3 of 3]
Excision date	Laterality

Source: NCI Genomic Data Commons file 0b7c6a89-748e-4fd0-ad3f-51c62303071c (TCGA-BR-8487.6720BDA7-1F6C-4426-9FA2-819D9318A736.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).